Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAQ6, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAQ6-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: Distal pancreas with spleen: Received is a 188 gram distal pancreatectomy and spleen measuring 14.5 (ML) x 11.5 (SI) x 5.8 (AP) cm, the pancreas measures 12 (ML) x 3 (SI) x 2.5 (AP) cm, the spleen measures

10.5 (SI) x 5.8 (AP) x 3.5 (ML) cm. There is an indurated white-yellow

lesion in the body of the pancreas [2 (ML) x 2 (AP) x 1.4 (SI) cm], and

pancreatic tissue distal to this looks atrophic. It is located

approximately 1 cm from the distal pancreatic margin. The tumor nodule is

greater than 5 cm from the spleen and does not grossly involve the splenic

artery or splenic vein. The spleen is serially sectioned and is grossly

normal. The splenic hilar fat and peripancreatic fat are searched for

lymph nodes.

ICD O-3

Adenocarcinoma, duct NOS 8500/3

Site: Pancreas tail 025.2

7/5/16/14

Microscopic Description:

Diagnosis Details: Invasive ductal adenocarcinoma, moderately differentiated

- Tumor arising in the tail of the pancreas and superficially invading peripancreatic fat
- Tumor measures 2.0 cm in greatest dimension
- Tumor approaches to less than 0.1 cm from peritonealized radial margin
- Pancreatic parenchymal and vascular margins free of tumor
- Extensive perineural invasion present
- No angiolymphatic invasion identified
- Six peripancreatic lymph nodes, negative for malignancy (0/6)
- Three splenic hilar lymph nodes, negative for malignancy (0/3)
- AJCC Pathologic Staging (7th edition): pT3 N0
- Moderate pancreatic intraepithelial neoplasia/PanIn 2

[page 2 of 2]
- Background chronic pancreatitis present
- Spleen and splenic vasculature, negative for malignancy

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Pancreatectomy and splenectomy

Tumor site: Tail

Tumor size: 2 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: 0/9 positive for metastasis (Regional 0/9)

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 178c816f-136d-4c4e-a776-7fb854464d41 (TCGA-FB-AAQ6.EF255DB8-CEE7-4882-B897-FA84696211D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).